Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8327, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8327-01A (Primary Tumor).

[page 1 of 3]
Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

Investigated for right pelvic pain and found to have a solid right renal mass.

Specimens Submitted:

1: SP: Right kidney

2: SP: Paracaval n

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CHROMOPHOBE CELL TYPE. THE TUMOR GREATEST DIAMETER IS 5.2 CM. THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY SHOWS A SIMPLE CYST (1 CM IN DIAMETER). THE ADRENAL GLAND IS NOT SUBMITTED.
- 2) LYMPH NODES, PARACAVAL; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).

Gross Description:

- 1) The specimen is received fresh for frozen section, labeled "Right kidney". It consists of a kidney, partially surrounded by yellow-tan, lobulated, perinephritic fatty tissue. The specimen weighs 420 grams and measures 12.0 x 7.0 x 5.0 cm. The kidney has a portion of ureter attached, measuring 7.5 cm in length and 0.4 cm in diameter. The ureter is probed, opened and shows a light tan, smooth and shiny inner surface. The kidney shows a smooth, shiny capsule. The specimen is bivalved. Approximately 0.4 cm close to the capsule in the center, attached to but not extending to the pelvis, there is a well-circumscribed, pink-dark

[page 2 of 3]
red homogeneous, soft tumor mass, measuring 5.0 x 5.2 x 4.3 cm. Approximately 1.3 cm from the capsule in the lower pole of the kidney is an oval cystic mass with a smooth surface, measuring 1.0 x 0.8 x 0.7 cm, containing dark brown fluid. The renal vein and artery are also probed and opened, showing a light tan, smooth and shiny inner surface. The rest of the kidney parenchyma is grossly unremarkable. Representative sections are submitted. Tissue is sent for [REDACTED] A photograph is taken.

Summary of Sections:

FSC - Frozen section control
UM - Ureteral margin
VM - Vascular margin
PLN - Possible lymph nodes
HF - Perihilar fat with kidney structure
CT - Relation tumor with kidney capsule
P - Pelvis with attached tumor
C - Representative section of cystic mass
T - Tumor
RS - Representative sections of normal kidney

[REDACTED]

2) The specimen is received in formalin, labeled "Paracaval lymph nodes". It consists of multiple irregular pieces of yellow-tan fibroadipose tissue, possibly containing lymph nodes, measuring 2.2 x 1.4 x 0.8 cm in aggregate. The specimen is submitted entirely.

Summary of Sections:

LN - Lymph nodes

Histo Stain Results/Comments:

Stain/Procedure Name	Result	Comment
CK7		
CD10		
IMMUNO RECUT		
NEGATIVE CONTROL		
CK7		
CK7		
NEGATIVE CONTROL		
IMMUNO RECUT		
CK7		
NEGATIVE CONTROL		
CK7		
CD10		
IMMUNO RECUT		
NEGATIVE CONTROL		

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	C		2	2	N
	CT		1	1	
	FSC		1	1	
	HF		2	2	
	P		2	2	
	PLN		2	M	
	RS		1	1	

[page 3 of 3]
T 2 2
UM 1 1
VM 1 M
2 LN 2 M Y

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. FAVOR CHROMOPHOBE RENAL CELL CARCINOMA. CASE DISCUSSED WITH DR.

PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file b60bb9d8-9cee-4629-b82a-70b06b68caa4 (TCGA-KL-8327.527B9836-1E08-48D7-BF13-CD58A0AC6318.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).